Somatic mutation profile of tumor specimen TCGA-AA-3655-01A (aliquot TCGA-AA-3655-01A-02D-1719-10) from TCGA case TCGA-AA-3655, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage II; Age at diagnosis: 68.2 years (24,896 days).
Specimen TCGA-AA-3655-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3c93f22f-d08a-455c-b564-0223bf38a59c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3655-11A (Solid Tissue Normal), aliquot TCGA-AA-3655-11A-01D-1719-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/14a94683-c72a-4864-8a31-5a00f14c8a64

The open-access MAF lists 91 somatic variants for this specimen: 66 protein-altering or splice-affecting, 21 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 21, Nonsense Mutation 5, Frame Shift Ins 4, Intron 3, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 25/42 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 23/34 reads (68%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRE2 | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 88/334 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as rs751834080, COSV100216508; called by mutect2, varscan2
- AKAP1 | c.997A>G p.R333G | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.152); catalogued as rs929690178, COSV58472424; called by muse, mutect2, varscan2
- AKAP3 | c.1030G>A p.V344I | Missense Mutation (SNP) | VAF 65/139 reads (47%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.679); catalogued as rs369931580, COSV99961755; called by muse, mutect2, varscan2
- ALDH1A3 | c.475G>T p.D159Y | Missense Mutation (SNP) | VAF 53/116 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV60902986; called by muse, mutect2, varscan2
- ALS2 | c.2222G>A p.R741Q | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.037); catalogued as rs753349655, COSV51891852; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AMER1 | c.1756C>T p.R586* | Nonsense Mutation (SNP) | VAF 54/59 reads (92%) | catalogued as COSV57666208; called by muse, mutect2, varscan2
- APC | c.4330C>T p.Q1444* | Nonsense Mutation (SNP) | VAF 27/43 reads (63%) | catalogued as CM995166, COSV57337884; called by muse, mutect2, varscan2
- CACNA1S | c.4600C>T p.R1534W | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs914458618, COSV62942978; called by muse, mutect2, varscan2
- CACNA2D1 | c.1887C>A p.Y629* (on ENST00000356253 / NM_001366867.1; = p.Y610* on NM_000722.4) | Nonsense Mutation (SNP) | VAF 19/99 reads (19%) | catalogued as COSV100667326; called by muse, mutect2, varscan2
- CHCHD1 | c.44A>G p.N15S | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.549); catalogued as COSV100863425; called by muse, mutect2, varscan2
- CHTOP | c.268C>T p.R90* | Nonsense Mutation (SNP) | VAF 21/56 reads (38%) | catalogued as rs1245949803, COSV64155031; called by muse, mutect2, varscan2
- CISH | c.736C>T p.R246C (on ENST00000348721 / NM_145071.4; = p.R263C on NM_013324.6) | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV62295470; called by muse, mutect2, varscan2
- COL5A1 | c.4043G>C p.G1348A | Missense Mutation (SNP) | VAF 96/197 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1060502252, COSV65665157; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COPS6 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57998598; called by muse, mutect2, varscan2
- CYP2D6 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 124/261 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as COSV62245308; called by muse, mutect2, varscan2
- DCDC1 | c.4717G>T p.D1573Y (on ENST00000597505 / NM_001367979.1; = p.D680Y on NM_020869.3) | Missense Mutation (SNP) | VAF 101/241 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58002772; called by muse, mutect2, varscan2
- DEGS2 | c.437C>G p.T146R | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV59785386; called by muse, mutect2, varscan2
- DGAT2 | c.967G>A p.D323N | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201842357, COSV57177259; called by muse, mutect2, varscan2
- DMTF1 | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV58687868; called by muse, mutect2, varscan2
- DOCK6 | c.3875T>C p.L1292P | Missense Mutation (SNP) | VAF 58/174 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV53921455; called by muse, mutect2
- DOK2 | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as rs768196912, COSV52389972, COSV52390495; called by muse, mutect2, varscan2
- FILIP1 | c.2542G>A p.E848K | Missense Mutation (SNP) | VAF 90/237 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.146); catalogued as COSV99386152; called by muse, mutect2, varscan2
- FILIP1 | c.1959G>C p.L653F | Missense Mutation (SNP) | VAF 82/183 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52739065; called by muse, mutect2, varscan2
- FILIP1 | c.1393G>A p.D465N | Missense Mutation (SNP) | VAF 69/186 reads (37%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.468); catalogued as COSV52739081; called by muse, mutect2, varscan2
- HYDIN | c.12319C>A p.Q4107K | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV101125224; called by muse, mutect2, varscan2
- IGHV6-1 | c.19A>G p.I7V | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs782343688; called by muse, mutect2, varscan2
- ITGA10 | c.2852G>A p.R951H | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.771); catalogued as rs782262690, COSV65198882; called by muse, mutect2, varscan2
- KIF26B | c.2111G>A p.R704H | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs757742040, COSV63641830; called by muse, mutect2, varscan2
- KLF15 | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.72); PolyPhen benign (0.267); catalogued as rs141580039, COSV56181050; called by muse, mutect2, varscan2
- KRT31 | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 68/148 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as rs1392380482, COSV52437822; called by muse, mutect2, varscan2
- L3MBTL1 | c.427C>T p.R143W (on ENST00000418998 / NM_001377303.1; = p.R53W on NM_015478.7) | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs1161853602, COSV64234591; called by muse, mutect2, varscan2
- MEFV | c.2110G>A p.V704I | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs104895096, CM012154, COSV54820562; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEB | c.15352C>T p.R5118W | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1282424661, COSV50843528; called by muse, mutect2, varscan2
- NFIC | c.1178C>T p.A393V | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV59413275; called by muse, mutect2, varscan2
- NOVA1 | c.682G>T p.E228* | Nonsense Mutation (SNP) | VAF 62/157 reads (39%) | catalogued as COSV99948756; called by muse, mutect2, varscan2
- NUGGC | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.966); catalogued as rs774319196, COSV58438380, COSV58439107; called by muse, mutect2, varscan2
- OPN4 | c.118G>A p.G40S | Missense Mutation (SNP) | VAF 53/60 reads (88%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as COSV54119096; called by muse, mutect2, varscan2
- OR10H2 | c.193G>A p.V65I | Missense Mutation (SNP) | VAF 67/179 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.03); catalogued as rs772844697, COSV59946866; called by muse, varscan2
- OR6N2 | c.781C>T p.R261W | Missense Mutation (SNP) | VAF 53/140 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs751838454, COSV59410585, COSV59412494; called by muse, mutect2, varscan2
- PARP9 | c.2128C>A p.Q710K | Missense Mutation (SNP) | VAF 74/182 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100831265; called by muse, mutect2, varscan2
- PCDH1 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as rs781258463, COSV54619670; called by muse, mutect2, varscan2
- PHF20 | c.1238C>T p.P413L | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs369867507; called by muse, mutect2, varscan2
- PLEKHH3 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV53190983; called by muse, mutect2
- PRR12 | c.469G>A p.A157T (on ENST00000615927; = p.A978T on NM_020719.3) | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs752530502, COSV101330792; called by muse, mutect2, varscan2
- RAP1GDS1 | c.565C>A p.L189M (on ENST00000408927 / NM_001100427.2; = p.L190M on NM_021159.5) | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.995); catalogued as COSV52791048; called by muse, mutect2, varscan2
- RICTOR | c.3404C>T p.T1135M | Missense Mutation (SNP) | VAF 69/181 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs371456052, COSV57119597; called by muse, mutect2, varscan2
- RIF1 | c.5134A>G p.T1712A | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV54622840; called by muse, mutect2, varscan2
- SBNO2 | c.1855C>T p.R619W | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771973175, COSV62323013; called by muse, mutect2, varscan2
- SGO2 | c.656T>C p.L219S | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as COSV100764800; called by muse, mutect2, varscan2
- SKIV2L | c.2591C>T p.S864L | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0.02); PolyPhen benign (0.353); catalogued as rs765832592, COSV61713288; called by muse, mutect2, varscan2
- SLIT3 | c.3938A>G p.N1313S | Missense Mutation (SNP) | VAF 79/214 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.091); catalogued as COSV60630108; called by muse, mutect2, varscan2
- STK33 | c.722T>G p.L241R | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100174526; called by muse, mutect2, varscan2
- STOX2 | c.626C>T p.T209M | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs900550747, COSV57855683; called by muse, mutect2, varscan2
- SUN5 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 57/161 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs556386557, COSV50063096, COSV50069780; called by muse, mutect2, varscan2
- TCF7L2 | c.1454dup p.C486Vfs*8 (on ENST00000355995 / NM_001367943.1; = p.C463Vfs*8 on NM_030756.5) | Frame Shift Ins (INS) | VAF 56/103 reads (54%) | catalogued as rs745872748, COSV53351350; called by mutect2, varscan2
- TRIM55 | c.1015G>A p.G339R | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT tolerated (0.68); PolyPhen benign (0.015); catalogued as rs776930378, COSV52545633; called by muse, varscan2
- URGCP | c.1936T>C p.F646L (on ENST00000453200 / NM_001077663.3; = p.F637L on NM_017920.4) | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.203); catalogued as COSV99787901; called by muse, mutect2, varscan2
- ZNF610 | c.1154C>T p.P385L | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs780673696, COSV58346295; called by muse, mutect2, varscan2
- ZNF75D | c.831G>T p.K277N | Missense Mutation (SNP) | VAF 98/110 reads (89%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.878); catalogued as COSV66133364; called by muse, mutect2, varscan2
- ZNF827 | c.2386A>G p.T796A | Missense Mutation (SNP) | VAF 61/142 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.024); catalogued as COSV65231050; called by muse, mutect2, varscan2
- CTNND1 | c.2397dup p.Q800Tfs*4 (on ENST00000399050 / NM_001085458.2; = p.Q794Tfs*4 on NM_001331.3) | Frame Shift Ins (INS) | VAF 15/43 reads (35%) | called by mutect2, pindel, varscan2
- ITGA7 | c.64dup p.L22Pfs*81 | Frame Shift Ins (INS) | VAF 55/134 reads (41%) | called by mutect2, pindel, varscan2
- ITPR3 | c.4892G>A p.G1631D | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.965); called by muse, mutect2
- STXBP3 | c.1695_1696insTT p.V566Lfs*3 | Frame Shift Ins (INS) | VAF 29/67 reads (43%) | called by mutect2, pindel, varscan2
- ABL2 | c.3303G>A p.T1101= (on ENST00000502732 / NM_007314.4; = p.T1086= on NM_005158.5) | Silent (SNP) | VAF 25/225 reads (11%) | catalogued as rs374740441, COSV100772406; called by muse, mutect2, varscan2
- ACP3 | c.1200G>A p.L400= | Silent (SNP) | VAF 40/115 reads (35%) | catalogued as rs988401924, COSV100668292, COSV63640995; called by muse, mutect2, varscan2
- ADAMTS7 | c.1656G>T p.R552= | Silent (SNP) | VAF 37/83 reads (45%) | catalogued as COSV66309155; called by muse, mutect2, varscan2
- APOB | c.8463G>A p.P2821= | Silent (SNP) | VAF 50/100 reads (50%) | catalogued as rs771976472, COSV51949382; ClinVar: likely benign; called by muse, mutect2, varscan2
- C8B | c.1458G>A p.R486= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as rs140570606; called by muse, mutect2, varscan2
- CHODL | c.771T>C p.S257= | Silent (SNP) | VAF 19/40 reads (48%) | catalogued as COSV53047379, COSV99517858; called by muse, mutect2, varscan2
- CLDN8 | c.435C>A p.I145= | Silent (SNP) | VAF 36/98 reads (37%) | catalogued as COSV54525707, COSV54527299; called by muse, mutect2
- DNAAF5 | c.2049G>A p.A683= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as COSV52414509; called by muse, mutect2, varscan2
- EGFL6 | c.318A>G p.Q106= | Silent (SNP) | VAF 69/78 reads (88%) | catalogued as COSV63060262; called by muse, mutect2, varscan2
- GLI3 | c.2757C>G p.L919= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV67894051; called by muse, mutect2, varscan2
- KIAA1109 | c.312C>A p.I104= | Silent (SNP) | VAF 72/201 reads (36%) | catalogued as COSV52689279; called by muse, mutect2, varscan2
- KL | c.2529T>C p.S843= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV101199205; called by muse, varscan2
- PCSK6 | c.2511C>T p.Y837= | Silent (SNP) | VAF 40/122 reads (33%) | catalogued as rs1359501549, COSV100624477; called by muse, mutect2, varscan2
- PIGF | c.186G>A p.V62= | Silent (SNP) | VAF 6/100 reads (6%) | called by muse, mutect2
- RALGAPA2 | c.1578A>G p.E526= | Silent (SNP) | VAF 111/272 reads (41%) | catalogued as rs1007769193, COSV52509003; called by muse, mutect2, varscan2
- SLC23A2 | c.396C>T p.Y132= | Silent (SNP) | VAF 46/86 reads (53%) | catalogued as rs578152528, COSV57778708; called by muse, mutect2, varscan2
- SLC36A3 | c.639C>T p.S213= | Silent (SNP) | VAF 13/120 reads (11%) | catalogued as rs1412783549, COSV58858081; called by muse, mutect2, varscan2
- SLITRK6 | c.2323C>T p.L775= | Silent (SNP) | VAF 88/253 reads (35%) | catalogued as COSV68391466; called by muse, mutect2, varscan2
- TBC1D10C | c.453G>A p.S151= | Silent (SNP) | VAF 28/78 reads (36%) | catalogued as rs773786261, COSV56702478; called by muse, mutect2, varscan2
- TRMT61A | c.438G>A p.E146= | Silent (SNP) | VAF 32/98 reads (33%) | catalogued as rs756301434, COSV54569717; called by muse, mutect2, varscan2
- VASH1 | c.843C>T p.D281= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as rs200857917, COSV51338620; called by muse, mutect2, varscan2
- AL109984.1 | n.186+1401C>T | Intron (SNP) | VAF 14/45 reads (31%) | catalogued as COSV63750729; called by muse, mutect2, varscan2
- CCDC140 | n.803C>A | RNA (SNP) | VAF 26/60 reads (43%) | catalogued as rs368710686, COSV54676600; called by muse, mutect2, varscan2
- DPF3 | c.871+3010G>A | Intron (SNP) | VAF 26/73 reads (36%) | catalogued as COSV63502683; called by muse, mutect2, varscan2
- OBSCN | c.18662-2948C>T | Intron (SNP) | VAF 15/45 reads (33%) | catalogued as COSV99484257; called by muse, mutect2, varscan2
